Gene-level copy-number profile of specimen HCM-CSHL-0090-C25-85A from HCMI case HCM-CSHL-0090-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.8 years (23,666 days).
Specimen HCM-CSHL-0090-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb7ace82-b2c8-4491-a986-d68803393bc1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0090-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/07b03f7e-ed72-4c88-aa3b-d5cb45aa7c9b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 205; copy number 2: 11,974; copy number 3: 29,352; copy number 4: 15,007; copy number 5: 778; copy number 6: 1,072; copy number 7: 7; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:16,174,680–16,231,992, 1 gene, copy number 7: GALNT15.
- chr18:23,503,470–23,956,222, 7 genes, copy number 7–8 (within-gene range 2–8): RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77.

Autosomal genes at a single copy (total copy number 1): 205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
